Somatic mutation profile of tumor specimen TCGA-AA-3975-01A (aliquot TCGA-AA-3975-01A-01W-0995-10) from TCGA case TCGA-AA-3975, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 80.2 years (29,310 days).
Specimen TCGA-AA-3975-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 266c81d9-eda3-45a0-b4fc-bcf2f97a9804.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3975-10A (Blood Derived Normal), aliquot TCGA-AA-3975-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5712617c-7d35-4397-93ea-bc44cf36884e

The open-access MAF lists 148 somatic variants for this specimen: 114 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 32, Nonsense Mutation 10, Splice Site 4, Nonstop Mutation 2, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 106/275 reads (39%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs121913462, CM077502, COSV57322511, COSV57366061, COSV57375983; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BNC2 | c.1723A>C p.S575R | Missense Mutation (SNP) | VAF 10/140 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1374823674, COSV66140362; called by muse, mutect2
- LCE1A | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 52/140 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV58726434, COSV58726966, COSV58727394; called by muse, mutect2, varscan2
- MAGEC1 | c.3138A>C p.K1046N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs753057119, COSV53569304, COSV53569381; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 53/81 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACOX1 | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 110/168 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1002618350, COSV99503283; called by muse, mutect2, varscan2
- ADAMTS12 | c.520T>G p.F174V | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV100710292; called by muse, mutect2, varscan2
- ADAMTS9 | c.4630G>T p.E1544* | Nonsense Mutation (SNP) | VAF 30/920 reads (3%) | catalogued as COSV55778103; called by muse, mutect2
- ADAMTSL3 | c.199A>C p.N67H | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99717000; called by muse, mutect2, varscan2
- ALDH1L2 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51553930; called by muse, mutect2, varscan2
- ANKRD6 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780403490, COSV60229575; called by muse, mutect2, varscan2
- ARFGAP1 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62262542; called by muse, mutect2
- ARFIP1 | c.923G>A p.R308H (on ENST00000353617 / NM_001287432.1; = p.R276H on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1187618928, COSV61883484; called by muse, mutect2, varscan2
- BACH2 | c.1291G>A p.V431M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777694816, COSV57586787; called by muse, mutect2, varscan2
- BCLAF1 | c.2114G>T p.S705I | Missense Mutation (SNP) | VAF 107/290 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV50357039; called by muse, mutect2, varscan2
- C1orf50 | c.299A>G p.H100R | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100998078; called by muse, mutect2, varscan2
- CATSPERD | c.1103A>T p.K368M | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100486654; called by muse, mutect2, varscan2
- CBLN4 | c.311A>T p.N104I | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV50352257; called by muse, mutect2, varscan2
- CDH9 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50321140; called by muse, mutect2
- CHL1 | c.1570C>A p.P524T (on ENST00000397491 / NM_001253387.1; = p.P540T on NM_006614.4) | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV99850147, COSV99852032; called by muse, varscan2
- CHL1 | c.1571C>A p.P524H (on ENST00000397491 / NM_001253387.1; = p.P540H on NM_006614.4) | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as COSV99850149; called by muse, varscan2
- CLCN1 | c.2902G>A p.D968N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs748630375, COSV100577719; called by muse, mutect2, varscan2
- CLEC2B | c.450A>C p.*150Yext*4 | Nonstop Mutation (SNP) | VAF 324/937 reads (35%) | catalogued as COSV57308801; called by muse, mutect2, varscan2
- CLTA | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 66/624 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99643531; called by muse, varscan2
- CNTN5 | c.44T>C p.M15T | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1230531422, COSV99673037; called by muse, mutect2, varscan2
- CPB1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs760474959, COSV51571965; called by muse, mutect2, varscan2
- DAAM1 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100658155; called by muse, mutect2, varscan2
- DAB2 | c.259G>T p.G87* | Nonsense Mutation (SNP) | VAF 13/247 reads (5%) | catalogued as COSV100297781; called by muse, mutect2
- DHX9 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841212; called by muse, mutect2, varscan2
- DNAH5 | c.7610-2A>C p.X2537_splice | Splice Site (SNP) | VAF 29/95 reads (31%) | catalogued as COSV99445210; called by muse, mutect2, varscan2
- DNAH8 | c.7948A>T p.T2650S | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV100543337; called by muse, mutect2, varscan2
- EFNA5 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs767938203, COSV60959932; called by muse, mutect2, varscan2
- EML5 | c.3828A>T p.K1276N | Missense Mutation (SNP) | VAF 82/150 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100715048; called by muse, varscan2
- EML5 | c.3827A>T p.K1276I | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100715049; called by muse, varscan2
- EML5 | c.3826A>T p.K1276* | Nonsense Mutation (SNP) | VAF 81/147 reads (55%) | catalogued as COSV100715050; called by muse, varscan2
- EPAS1 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1425417808, COSV99762913; called by muse, mutect2
- ERAL1 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54739367; called by muse, mutect2
- FAM110B | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs765086827, COSV64064133; called by muse, mutect2
- FCGR1A | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs374578876; called by muse, mutect2, varscan2
- FIP1L1 | c.1178T>A p.F393Y | Missense Mutation (SNP) | VAF 156/514 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.827); catalogued as COSV60994425; called by muse, varscan2
- FIP1L1 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 150/507 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60994449; called by muse, varscan2
- FLNC | c.850+1G>T p.X284_splice | Splice Site (SNP) | VAF 12/20 reads (60%) | catalogued as COSV100367637; called by muse, mutect2, varscan2
- GUF1 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 21/267 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55783438; called by muse, mutect2
- HAVCR1 | c.1093T>C p.*365Qext*12 | Nonstop Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as rs776039147, COSV59398475; called by muse, mutect2, varscan2
- HEATR3 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53528503; called by muse, mutect2, varscan2
- HIPK4 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs773591468, COSV52519635; called by muse, mutect2, varscan2
- HOXB7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770931876, COSV53310001; called by muse, mutect2, varscan2
- IGSF1 | c.3103C>T p.R1035C | Missense Mutation (SNP) | VAF 195/225 reads (87%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs750269789, COSV100811831; called by muse, mutect2, varscan2
- IGSF3 | c.1732G>A p.V578M (on ENST00000369486 / NM_001007237.3; = p.V598M on NM_001542.4) | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149872697; called by muse, mutect2, varscan2
- IKBKB | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1563353425, COSV100645584; called by muse, mutect2
- IL10RA | c.872A>T p.D291V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV57139964; called by muse, mutect2, varscan2
- IQGAP3 | c.4204A>T p.K1402* | Nonsense Mutation (SNP) | VAF 84/210 reads (40%) | catalogued as COSV63250034; called by muse, mutect2, varscan2
- KCNJ3 | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV99715263; called by muse, mutect2, varscan2
- KLHL38 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs374238365, COSV58086309; called by muse, mutect2, varscan2
- KRAS | c.204G>T p.R68S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55640563, COSV55650115; called by muse, mutect2, varscan2
- KRT73 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs199866943, COSV59838192, COSV59838247, COSV99988578; called by muse, mutect2, varscan2
- LCP1 | c.896A>T p.Y299F | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs779555319, COSV100549690; called by muse, mutect2
- LOXL3 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.291); catalogued as rs758787890, COSV51206406; called by muse, mutect2, varscan2
- MASP1 | c.1530C>A p.S510R | Missense Mutation (SNP) | VAF 188/467 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100536795; called by muse, mutect2, varscan2
- MCM4 | c.598-1G>A p.X200_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100031263; called by muse, mutect2, varscan2
- MICAL2 | c.1970C>T p.T657I | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV99816723; called by muse, mutect2, varscan2
- MUC16 | c.29686G>T p.A9896S | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.014); catalogued as COSV101198134; called by muse, mutect2, varscan2
- MYO16 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 117/237 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775498997, COSV51805272; called by muse, mutect2, varscan2
- MYOF | c.6104T>A p.L2035H | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100825234; called by muse, mutect2, varscan2
- NCAN | c.3361G>A p.G1121S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376145430; called by muse, varscan2
- NPY1R | c.979T>G p.F327V | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56713714, COSV56716428; called by muse, mutect2, varscan2
- NVL | c.2521A>C p.K841Q | Missense Mutation (SNP) | VAF 211/650 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.07); catalogued as COSV99893712; called by muse, mutect2, varscan2
- OSBPL8 | c.2021A>C p.K674T | Missense Mutation (SNP) | VAF 81/686 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.062); catalogued as COSV53879469; called by muse, mutect2, varscan2
- PCNX2 | c.3840C>T p.L1280= | Splice Region (SNP) | VAF 25/58 reads (43%) | catalogued as rs746899040, COSV50785748; called by muse, mutect2, varscan2
- PGK1 | c.107A>C p.N36T | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as rs141397576, COSV64831736; called by muse, mutect2, varscan2
- POP1 | c.1739T>G p.L580R | Missense Mutation (SNP) | VAF 301/1346 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100855639; called by muse, mutect2, varscan2
- POT1 | c.498T>A p.C166* | Nonsense Mutation (SNP) | VAF 16/224 reads (7%) | catalogued as COSV100713997; called by muse, mutect2
- PRIM2 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 174/479 reads (36%) | catalogued as rs951594572, COSV51424460; called by muse, mutect2, varscan2
- PRKD1 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1274583081, COSV59561520, COSV59569146; called by muse, varscan2
- PRR16 | c.479C>A p.P160Q (on ENST00000407149 / NM_001300783.2; = p.P137Q on NM_016644.2) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV65395149, COSV65399812; called by muse, mutect2, varscan2
- RNF165 | c.1021C>A p.Q341K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV53971898; called by muse, mutect2, varscan2
- RNF213 | c.9334C>G p.L3112V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100299746, COSV60392235; called by muse, mutect2, varscan2
- SDK1 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778421749, COSV101268789; called by muse, mutect2, varscan2
- SDK2 | c.2412T>G p.N804K | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101166840; called by muse, mutect2, varscan2
- SEMG1 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV54872079; called by muse, mutect2, varscan2
- SEMG2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs929540146, COSV65647288; called by muse, mutect2
- SETD5 | c.1305T>G p.I435M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV56708435; called by muse, mutect2, varscan2
- SLC16A7 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.98); PolyPhen benign (0.014); catalogued as rs759736305, COSV53892756; called by muse, mutect2, varscan2
- SLC38A4 | c.1445G>C p.G482A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99872458; called by muse, mutect2
- SLCO1B3 | c.1649C>G p.T550R | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV99680797; called by muse, mutect2, varscan2
- SLITRK1 | c.1722T>A p.N574K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs763494516, COSV100999785; called by muse, mutect2, varscan2
- SMPDL3B | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs145333269; called by muse, mutect2, varscan2
- SNPH | c.8T>A p.M3K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); catalogued as COSV67870294; called by muse, mutect2, varscan2
- SPON2 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335104; called by mutect2, varscan2
- SPTA1 | c.5269C>T p.R1757C | Missense Mutation (SNP) | VAF 113/418 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754598605, COSV63754961; called by muse, mutect2, varscan2
- STAG1 | c.2852G>T p.G951V | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV99364450; called by muse, mutect2
- STK4 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 94/602 reads (16%) | catalogued as COSV65669582; called by muse, mutect2, varscan2
- TENM4 | c.4662C>A p.D1554E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1033019883, COSV53614670; called by muse, mutect2
- TIAM1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs970048985, COSV99732887; called by muse, mutect2, varscan2
- TMCO5A | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100148436; called by muse, mutect2, varscan2
- TMEM79 | c.979T>C p.Y327H | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55293674; called by muse, mutect2, varscan2
- TNFAIP3 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52797263; called by muse, mutect2, varscan2
- TRMT2B | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 95/114 reads (83%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs758839212, COSV58618716; called by muse, mutect2, varscan2
- TTN | c.62522G>A p.R20841Q (on ENST00000591111; = p.R13417Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | PolyPhen possibly damaging (0.514); catalogued as rs200146608, COSV100621113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5D | c.107C>G p.T36S | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99772269; called by muse, mutect2
- UPK1B | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs763183222, COSV51766408; called by muse, mutect2, varscan2
- USP9Y | c.773+2T>G p.X258_splice | Splice Site (SNP) | VAF 40/49 reads (82%) | catalogued as COSV100168199; called by muse, mutect2, varscan2
- VPS8 | c.1942T>A p.L648I (on ENST00000625842 / NM_001349294.1; = p.L646I on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV99800747; called by muse, varscan2
- XIRP2 | c.5926A>G p.K1976E (on ENST00000628543; = p.K2151E on NM_152381.6) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99738628; called by muse, mutect2, varscan2
- ZDHHC14 | c.734T>A p.L245H | Missense Mutation (SNP) | VAF 82/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58193384; called by muse, mutect2, varscan2
- ZFC3H1 | c.3127C>T p.R1043* | Nonsense Mutation (SNP) | VAF 98/283 reads (35%) | catalogued as COSV101110323; called by muse, mutect2, varscan2
- ZNF429 | c.1510A>G p.S504G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV61914912; called by muse, mutect2
- ZNF473 | c.1039T>C p.Y347H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs143412784; called by muse, mutect2, varscan2
- ZUP1 | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as COSV63944118; called by muse, mutect2
- ZUP1 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV63944123; called by muse, mutect2
- CCN6 | c.746T>C p.I249T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2
- IGKV2-24 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SOS2 | c.1879A>G p.T627A | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- ADRA1A | c.489C>T p.F163= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV52358685; called by muse, mutect2, varscan2
- ATP10A | c.1473G>A p.R491= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV63514764; called by muse, mutect2, varscan2
- BCKDK | c.1209C>T p.I403= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs377552512; called by muse, mutect2, varscan2
- CCL7 | c.6A>G p.K2= | Silent (SNP) | VAF 44/202 reads (22%) | catalogued as COSV52336703, COSV52337407; called by muse, mutect2, varscan2
- CCSAP | c.801G>A p.S267= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as rs1395421637, COSV52909206; called by muse, mutect2
- COL5A3 | c.4242G>A p.P1414= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs537422545, COSV99318247; called by muse, mutect2, varscan2
- DYNC2I1 | c.2253C>T p.S751= | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as rs1563181378, COSV101337608; called by muse, mutect2
- EZHIP | c.1509G>A p.P503= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as rs1166138684, COSV100539483; called by muse, mutect2, varscan2
- GPX6 | c.18G>A p.Q6= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV62657083; called by muse, mutect2, varscan2
- HCN1 | c.2208G>A p.Q736= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV57497937; called by muse, mutect2, varscan2
- LCP1 | c.894T>A p.A298= | Silent (SNP) | VAF 17/190 reads (9%) | catalogued as COSV100549693; called by muse, mutect2
- LILRB1 | c.1131C>T p.N377= (on ENST00000427581; = p.N341= on NM_006669.6) | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as rs201120319; called by muse, mutect2, varscan2
- MYO18A | c.6072C>T p.H2024= | Silent (SNP) | VAF 45/158 reads (28%) | catalogued as rs567111157, COSV62863758; called by muse, mutect2, varscan2
- NHLRC1 | c.639C>A p.G213= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV61481263; called by muse, mutect2, varscan2
- PRELP | c.84C>T p.P28= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs562945346, COSV58115201; called by muse, mutect2, varscan2
- PTEN | c.516G>A p.R172= | Silent (SNP) | VAF 52/160 reads (33%) | catalogued as COSV64292032; called by muse, mutect2, varscan2
- RAB5B | c.507C>T p.N169= | Silent (SNP) | VAF 35/467 reads (7%) | catalogued as rs199813423, COSV64364705, COSV64365137; called by muse, mutect2
- RBM15B | c.2595C>T p.Y865= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs782499499; called by muse, mutect2
- RELT | c.504C>T p.I168= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs552980658, COSV50361049; called by muse, mutect2, varscan2
- ROBO1 | c.3174G>A p.L1058= | Silent (SNP) | VAF 106/284 reads (37%) | catalogued as COSV71392419; called by muse, mutect2, varscan2
- ROS1 | c.5178T>C p.N1726= | Silent (SNP) | VAF 167/432 reads (39%) | catalogued as COSV63852628; called by muse, mutect2, varscan2
- RXFP2 | c.585C>T p.N195= | Silent (SNP) | VAF 184/1934 reads (10%) | catalogued as rs766621937, COSV53633834; called by muse, mutect2
- SF3B2 | c.513G>A p.S171= | Silent (SNP) | VAF 119/365 reads (33%) | catalogued as rs201233817; called by muse, mutect2, varscan2
- SLC25A37 | c.402C>T p.D134= | Silent (SNP) | VAF 49/72 reads (68%) | catalogued as rs568296478, COSV51563126, COSV51563487; called by muse, mutect2, varscan2
- SLC4A4 | c.1690C>T p.L564= (on ENST00000264485 / NM_001098484.3; = p.L520= on NM_003759.4) | Silent (SNP) | VAF 63/792 reads (8%) | catalogued as COSV52617498; called by muse, mutect2
- SLCO3A1 | c.915C>T p.S305= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs367736458; called by muse, mutect2, varscan2
- SPACA1 | c.543C>T p.F181= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs201338817, COSV52759252; called by muse, mutect2, varscan2
- SYT14 | c.1653G>A p.A551= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs371789098; ClinVar: likely benign; called by muse, mutect2, varscan2
- TFAP2A | c.291C>G p.G97= (on ENST00000482890; = p.G89= on NM_001032280.3) | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV60231767; called by muse, mutect2, varscan2
- TIMM23 | c.21C>T p.S7= | Silent (SNP) | VAF 45/134 reads (34%) | called by muse, mutect2, varscan2
- TUBA8 | c.355C>T p.L119= | Silent (SNP) | VAF 50/61 reads (82%) | catalogued as COSV57812521; called by muse, mutect2, varscan2
- TYR | c.237G>A p.S79= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs376813190; called by muse, mutect2, varscan2
- ATP6AP1L | n.1887C>T | RNA (SNP) | VAF 49/104 reads (47%) | catalogued as COSV101205093; called by muse, mutect2, varscan2
- DST | c.4297-1480C>T | Intron (SNP) | VAF 34/89 reads (38%) | catalogued as rs754482991, COSV99751235; ClinVar: likely benign; called by muse, mutect2, varscan2
